Somatic mutation profile of tumor specimen C3N-02928-01 (aliquot CPT0184670007) from CPTAC case C3N-02928, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 65.0 years (23,733 days).
Specimen C3N-02928-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61187535-c6dd-4896-bd40-ac898056c552.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02928-31 (Blood Derived Normal), aliquot CPT0184730002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eda7db64-7d2e-449d-80e6-e799b1d239f8

The open-access MAF lists 126 somatic variants for this specimen: 82 protein-altering or splice-affecting, 27 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 27, Intron 9, Frame Shift Del 5, Nonsense Mutation 3, 3'UTR 3, 5'UTR 3, Splice Site 2, RNA 1, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 94/462 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- AXIN2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1244431726, COSV100195707; called by muse, mutect2, varscan2
- DNAH7 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs370166766; called by mutect2, varscan2
- EGFR | c.2500G>C p.V834L | Missense Mutation (SNP) | VAF 60/364 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs397517127, COSV51767386, COSV51777202; ClinVar: uncertain significance; called by muse, varscan2
- ESYT1 | c.1820C>T p.T607M | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs762007691, COSV57277475; called by muse, mutect2, varscan2
- FAT4 | c.4131dup p.L1378Tfs*4 | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs776607295; called by mutect2, varscan2
- GCLC | c.843G>C p.L281F (on ENST00000643939; = p.L279F on NM_001498.4) | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99037981; called by muse, mutect2, varscan2
- KBTBD8 | c.1093C>A p.H365N | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.988); catalogued as COSV55129689; called by muse, mutect2, varscan2
- KCP | c.1165G>A p.A389T (on ENST00000620378; = p.A446T on NM_001366122.1) | Missense Mutation (SNP) | VAF 46/289 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs1036664168; called by muse, mutect2, varscan2
- LCT | c.3916G>C p.D1306H | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1489231732, COSV51544059; called by muse, mutect2
- OLFML3 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs752080024; called by muse, mutect2, varscan2
- OR2M2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 45/364 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV62897836, COSV62897885; called by muse, mutect2, varscan2
- OR3A3 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99351611; called by muse, mutect2, varscan2
- PATE2 | c.186T>G p.F62L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV62069245; called by muse, mutect2, varscan2
- PCK2 | c.1112G>A p.S371N | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs766537338; called by muse, mutect2, varscan2
- PDE10A | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs768772986; called by muse, mutect2, varscan2
- PPM1K | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 33/418 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV55797473; called by muse, mutect2
- PRSS58 | c.359C>G p.A120G | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs147651633; called by muse, mutect2, varscan2
- RABGGTB | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV54200547; called by muse, mutect2, varscan2
- ROBO1 | c.4933G>A p.E1645K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV71392517; called by muse, mutect2
- RP1L1 | c.1589G>T p.G530V | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs374232439; called by muse, mutect2, varscan2
- SLC37A3 | c.1468C>A p.H490N (on ENST00000326232 / NM_001363375.1; = p.S389* on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/333 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as CM137611, COSV58265819; called by muse, mutect2, varscan2
- SLC9A9 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV57219683; called by muse, mutect2, varscan2
- SOX9 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 53/437 reads (12%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.883); catalogued as rs1298811626, COSV99818441; called by muse, mutect2, varscan2
- TFAP2A | c.687C>G p.Y229* (on ENST00000482890; = p.Y221* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 51/239 reads (21%) | catalogued as COSV100117306; called by muse, mutect2, varscan2
- TMPRSS5 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs202148348; called by muse, mutect2
- TRPM1 | c.1507-1G>C p.X503_splice | Splice Site (SNP) | VAF 33/357 reads (9%) | catalogued as COSV56630027; called by muse, mutect2
- WDR72 | c.2585T>C p.L862S | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV64754113; called by muse, mutect2, varscan2
- ZNF496 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 88/765 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs778466446; called by muse, mutect2, varscan2
- ACSM2B | c.1544T>A p.F515Y | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- AHCYL2 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- AHNAK2 | c.10058C>A p.T3353N | Missense Mutation (SNP) | VAF 14/502 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2
- ATG9A | c.2131C>T p.L711F | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- BABAM1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- BRDT | c.818T>A p.L273* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
- C1orf87 | c.717G>T p.Q239H | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- CCDC168 | c.3539A>T p.Y1180F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- CCDC85C | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 37/382 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDK16 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CLC | c.227T>C p.V76A | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CYP2F1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2
- DLGAP3 | c.2750C>G p.P917R | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DLGAP3 | c.2356G>C p.G786R | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EYS | c.432del p.T145Hfs*21 | Frame Shift Del (DEL) | VAF 19/162 reads (12%) | called by mutect2, pindel, varscan2
- FEM1B | c.49G>T p.V17L | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by mutect2, varscan2
- FLG2 | c.1256A>T p.Y419F | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- GAPVD1 | c.637G>C p.D213H | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GATA4 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.06); called by muse, mutect2
- HERC2 | c.2087A>T p.H696L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HIPK2 | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KCTD3 | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KIF18B | c.1810del p.L604Cfs*55 (on ENST00000593135 / NM_001265577.2; = p.L616Cfs*55 on NM_001264573.2) | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- LILRB2 | c.1503C>A p.F501L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MAP4K4 | c.198C>G p.I66M | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MMAB | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 11/392 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.018); called by muse, mutect2
- MYH10 | c.5260C>A p.L1754M | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- NPHP1 | c.1222_1247del p.R408Gfs*15 (on ENST00000393272 / NM_207181.4; = p.R409Gfs*15 on NM_000272.5) | Frame Shift Del (DEL) | VAF 20/189 reads (11%) | called by mutect2, pindel
- OR2L2 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR2T4 | c.285C>G p.I95M | Missense Mutation (SNP) | VAF 38/484 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- OR4N2 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PABPC1L2A | c.32C>A p.P11H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PABPC1L2A | c.31C>G p.P11A | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, varscan2
- PI16 | c.1389C>G p.F463L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); called by muse, mutect2
- POLR1F | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, varscan2
- PRMT1 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT tolerated (0.3); PolyPhen probably damaging (1); called by muse, mutect2
- RB1 | c.1740del p.G581Dfs*30 | Frame Shift Del (DEL) | VAF 32/157 reads (20%) | called by mutect2, pindel, varscan2
- RELCH | c.3115-1G>C p.X1039_splice | Splice Site (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- SMARCC2 | c.2436G>C p.K812N | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SNX27 | c.412C>T p.H138Y | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRXN1 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 29/319 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- SYNE1 | c.18706-6G>C | Splice Region (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- SYNPO | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- TAB3 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THOC7 | c.486G>C p.L162F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.388); called by muse, mutect2
- TJP1 | c.2929C>G p.P977A | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM49B | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 53/305 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TSHZ3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VCAN | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- ZNF460 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF469 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 32/307 reads (10%) | called by muse, mutect2, varscan2
- ZNF615 | c.1695_1696del p.K566Tfs*6 | Frame Shift Del (DEL) | VAF 20/152 reads (13%) | called by pindel, varscan2
- ZNF615 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ACOT11 | c.1071G>A p.K357= | Silent (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS4 | c.915G>A p.S305= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs150760814, COSV63488228; called by muse, mutect2, varscan2
- ANKRD30B | c.3135G>T p.V1045= | Silent (SNP) | VAF 6/89 reads (7%) | catalogued as COSV100271660; called by muse, mutect2
- APOBEC3D | c.585C>T p.R195= | Silent (SNP) | VAF 40/219 reads (18%) | catalogued as rs760027760; called by muse, mutect2, varscan2
- ATP2B3 | c.111C>G p.L37= | Silent (SNP) | VAF 21/226 reads (9%) | called by muse, mutect2
- C11orf96 | c.1083G>A p.P361= (on ENST00000339446; = p.P48= on NM_001145033.2) | Silent (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- CFAP94 | c.1980G>A p.E660= (on ENST00000320267 / NM_001352064.2; = p.E666= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- CHST12 | c.498C>T p.I166= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- CTCFL | c.1449G>A p.E483= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV99712183, COSV99713525; called by muse, mutect2, varscan2
- DDX42 | c.2331G>T p.V777= | Silent (SNP) | VAF 38/177 reads (21%) | called by muse, mutect2, varscan2
- FAT3 | c.11991G>A p.P3997= | Silent (SNP) | VAF 59/294 reads (20%) | catalogued as COSV53070778, COSV53133042; called by muse, mutect2, varscan2
- GALC | c.183C>A p.V61= | Silent (SNP) | VAF 37/269 reads (14%) | catalogued as COSV54325384; called by muse, mutect2, varscan2
- HK3 | c.81A>T p.S27= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- ITGA2B | c.2739G>T p.S913= | Silent (SNP) | VAF 51/364 reads (14%) | catalogued as COSV52232056; called by muse, mutect2, varscan2
- KCNJ1 | c.693G>A p.L231= | Silent (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- MRNIP | c.555A>T p.T185= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5739C>T p.F1913= | Silent (SNP) | VAF 36/444 reads (8%) | called by muse, mutect2
- RAPGEF5 | c.303C>G p.L101= (on ENST00000401957 / NM_001367602.2; = p.L404= on NM_012294.5) | Silent (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- RNF41 | c.336G>T p.R112= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, varscan2
- SRL | c.1134C>T p.F378= | Silent (SNP) | VAF 19/303 reads (6%) | called by muse, mutect2
- SYT8 | c.414G>C p.L138= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- TMEM108 | c.1338C>T p.N446= | Silent (SNP) | VAF 17/133 reads (13%) | called by muse, mutect2, varscan2
- TNFRSF9 | c.321A>G p.K107= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- TOMM70 | c.216C>T p.G72= | Silent (SNP) | VAF 48/236 reads (20%) | catalogued as rs749745081; called by muse, mutect2, varscan2
- TRIM75P | c.642G>A p.Q214= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- UTP25 | c.1113C>T p.L371= | Silent (SNP) | VAF 18/326 reads (6%) | called by muse, mutect2
- ZNF689 | c.1446A>G p.P482= | Silent (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- ACBD5 | c.-38T>G | 5'UTR (SNP) | VAF 10/86 reads (12%) | called by muse, varscan2
- APP | c.1090+28G>A | Intron (SNP) | VAF 16/242 reads (7%) | catalogued as rs1233758291; called by muse, mutect2
- APRT | c.187+50G>A | Intron (SNP) | VAF 21/243 reads (9%) | called by muse, mutect2
- CHRNA4 | c.*3222G>A | 3'UTR (SNP) | VAF 27/317 reads (9%) | catalogued as rs1248201212; called by muse, mutect2
- COL4A2 | c.1340-349G>A | Intron (SNP) | VAF 236/921 reads (26%) | catalogued as rs1251863941; called by muse, varscan2
- EFHC1 | c.*399C>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- MYO15A | c.-34C>T | 5'UTR (SNP) | VAF 23/218 reads (11%) | catalogued as rs374326586; called by muse, mutect2, varscan2
- NSG2 | c.*76G>C | 3'UTR (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100292934; called by muse, mutect2, varscan2
- PHLDB2 | c.1336-1676T>G | Intron (SNP) | VAF 56/258 reads (22%) | called by muse, mutect2, varscan2
- PRDX2 | c.257+69C>A | Intron (SNP) | VAF 6/180 reads (3%) | catalogued as COSV56878632; called by muse, mutect2
- RN7SL214P | chr15:77915878 C>A | 3'Flank (SNP) | VAF 97/612 reads (16%) | called by muse, mutect2, varscan2
- SPINDOC | c.934+3625C>T | Intron (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2, varscan2
- SREBF1 | c.2383+15C>G | Intron (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- TLE4 | c.46-399G>T | Intron (SNP) | VAF 6/37 reads (16%) | catalogued as rs753169876; called by muse, mutect2, varscan2
- TMEM78 | n.331C>T | RNA (SNP) | VAF 16/249 reads (6%) | catalogued as COSV60074089; called by muse, mutect2
- TNS2 | c.1226-17C>G | Intron (SNP) | VAF 49/279 reads (18%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.-18G>A | 5'UTR (SNP) | VAF 13/206 reads (6%) | called by muse, mutect2
